Somatic mutation profile of tumor specimen TCGA-LN-A7HX-01A (aliquot TCGA-LN-A7HX-01A-11D-A33E-09) from TCGA case TCGA-LN-A7HX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.6 years (26,517 days).
Specimen TCGA-LN-A7HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b93e33a3-0978-45d9-8f80-cf92bbb0f422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A7HX-10A (Blood Derived Normal), aliquot TCGA-LN-A7HX-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c54bfc80-ba08-4a64-97bc-821d8ffa106d

The open-access MAF lists 120 somatic variants for this specimen: 81 protein-altering or splice-affecting, 30 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 30, Intron 5, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKRD36B | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV51535666; called by muse, mutect2, varscan2
- APCDD1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1220087910, COSV62372715; called by muse, mutect2, varscan2
- ARHGEF2 | c.2570G>A p.R857Q (on ENST00000361247 / NM_001162383.2; = p.R829Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs533748068; called by muse, mutect2
- ATP10D | c.1477A>G p.M493V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV56713380; called by muse, mutect2, varscan2
- BCAT2 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs772311929; called by muse, mutect2, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs539297455, COSV54625370; called by pindel, varscan2
- CCNK | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs759957278, COSV66274945; called by muse, mutect2, varscan2
- DCDC1 | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs773544052; called by muse, mutect2
- DPPA2 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs1191842575; called by muse, mutect2, varscan2
- FBXO15 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs748658162, COSV54043488; called by muse, mutect2, varscan2
- FHOD1 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs774658881; called by muse, mutect2, varscan2
- GRIP2 | c.333C>T p.D111= (on ENST00000619221; = p.D14= on NM_001080423.4) | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs369716360; called by mutect2, varscan2
- HELB | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs772072453; called by muse, mutect2, varscan2
- IGSF9 | c.1046A>G p.N349S (on ENST00000368094 / NM_001135050.2; = p.N333S on NM_020789.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1488345337; called by muse, mutect2, varscan2
- IL5RA | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56521979; called by muse, mutect2, varscan2
- ITGA6 | c.1061C>T p.S354L (on ENST00000442250; = p.S315L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51219451; called by muse, mutect2, varscan2
- KLK12 | c.127A>C p.T43P | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs747067935; called by muse, mutect2, varscan2
- MAPK1 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53189955; called by muse, mutect2, varscan2
- MAPKBP1 | c.1027A>G p.R343G (on ENST00000456763 / NM_001128608.2; = p.R337G on NM_014994.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1000578177; called by muse, mutect2, varscan2
- MARCHF10 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs200814272, COSV60888723; called by muse, mutect2, varscan2
- MDM2 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50701997; called by muse, mutect2, varscan2
- MRPS34 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV51598737; called by muse, mutect2, varscan2
- MTHFD1L | c.2053A>G p.I685V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780895264; called by muse, mutect2, varscan2
- PCDHA9 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs140634296; called by muse, mutect2, varscan2
- PLCG1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54819610; called by muse, mutect2
- PPP2R5B | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1315924261; called by muse, mutect2, varscan2
- SFTPA1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100957100; called by muse, mutect2, varscan2
- TBC1D31 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs757300043, COSV99782809; called by muse, mutect2, varscan2
- THBS4 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as rs553602331, COSV63470130; called by muse, mutect2, varscan2
- TP53 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM942119, COSV52688040, COSV52961532, COSV53198425; called by muse, mutect2, varscan2
- TP63 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV53199044; called by muse, mutect2, varscan2
- WDFY3 | c.2429G>C p.R810T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.278); catalogued as COSV55693821; called by muse, mutect2, varscan2
- YLPM1 | c.3542A>G p.Y1181C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.298); catalogued as rs748123589; called by muse, mutect2, varscan2
- ZFHX4 | c.8656T>G p.F2886V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs773766567; called by muse, mutect2, varscan2
- ZSCAN5B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as rs185491243; called by muse, mutect2, varscan2
- AASDH | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ABCA8 | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC9 | c.2399G>C p.G800A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP002748.5 | c.884A>C p.D295A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CENPC | c.2554A>T p.K852* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- CLCN2 | c.814G>C p.V272L | Missense Mutation (SNP) | VAF 88/100 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CNNM2 | c.2249C>G p.P750R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- COPB1 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA3 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCDC1 | c.2185A>G p.K729E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DMD | c.5054A>G p.D1685G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHB4 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.9605_9607del p.N3202del | In Frame Del (DEL) | VAF 8/72 reads (11%) | called by pindel, varscan2
- FDFT1 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- GBP1 | c.1337del p.K446Sfs*20 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | called by mutect2, pindel, varscan2
- GNAQ | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GOLGA3 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR52 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDO1 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549 | c.5846A>G p.H1949R (on ENST00000422774 / NM_001164665.2; = p.H1933R on NM_020910.3) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF2B | c.733A>T p.M245L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP1B | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MAP7D2 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MAT2B | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGP | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NAV3 | c.5527G>C p.E1843Q (on ENST00000397909 / NM_001024383.2; = p.E1821Q on NM_014903.6) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEB | c.19410C>A p.D6470E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); called by muse, mutect2
- NECTIN3 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NLRP14 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NOC4L | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- PLEC | c.2756C>T p.S919L (on ENST00000322810 / NM_201380.4; = p.S809L on NM_000445.5) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU2F1 | c.517G>C p.A173P (on ENST00000541643 / NM_001365848.1; = p.A196P on NM_002697.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- POU3F3 | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- PRDM16 | c.3655G>C p.E1219Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPN2 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM15 | c.1379G>C p.G460A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN2A | c.4155G>C p.E1385D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SET | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TJP1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFAIP6 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UBE2O | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMIZ1 | c.3109C>G p.L1037V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF585B | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF655 | c.363_373delinsT p.E121Dfs*41 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by pindel, varscan2*
- ZNF750 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AP002512.3 | c.516G>A p.A172= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs770156394; called by mutect2, varscan2
- ARHGAP17 | c.1503G>A p.K501= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- BCL9 | c.1572A>G p.E524= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- CACNA1H | c.3987C>T p.S1329= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs770769436, COSV62001478; called by muse, mutect2, varscan2
- CACNB3 | c.351C>T p.F117= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.1824T>G p.G608= (on ENST00000236925 / NM_001297707.2; = p.G597= on NM_203459.3) | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- CCNL2 | c.552C>G p.L184= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CELF6 | c.289C>A p.R97= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs377177378, COSV99763499; called by muse, varscan2
- DAPP1 | c.564G>T p.L188= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs975003374; called by muse, mutect2, varscan2
- DNAJC2 | c.1275G>A p.E425= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV50786902; called by muse, mutect2, varscan2
- ERVW-1 | c.1002T>C p.G334= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1335731819; called by muse, mutect2, varscan2
- FAT4 | c.6195T>C p.I2065= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- GABBR1 | c.1209C>A p.I403= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- GRIA2 | c.2211G>A p.K737= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- HMCN1 | c.1818C>G p.L606= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- KDM5B | c.453A>G p.K151= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- LRCH2 | c.1443G>A p.L481= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- NRCAM | c.378G>A p.R126= (on ENST00000379028 / NM_001371124.1; = p.R120= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.261G>A p.A87= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1314899957, COSV53972199; called by muse, mutect2, varscan2
- PLCE1 | c.3987C>G p.L1329= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- POGLUT3 | c.882C>G p.L294= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- PRKAA1 | c.816T>C p.D272= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- PSD4 | c.951C>T p.T317= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- SLC12A8 | c.1239C>A p.T413= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- SSNA1 | c.279C>A p.L93= | Silent (SNP) | VAF 34/51 reads (67%) | called by muse, mutect2, varscan2
- UFL1 | c.2220C>G p.V740= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- VPS33B | c.882C>T p.F294= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60980196; called by muse, mutect2
- VSX1 | c.759C>T p.L253= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ZNF626 | c.255T>G p.L85= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- ZNF629 | c.1734C>T p.F578= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1459431097; called by muse, mutect2
- AL662899.2 | c.367+283C>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- FBXL12 | c.-2T>C | 5'UTR (SNP) | VAF 7/47 reads (15%) | catalogued as rs764094932; called by muse, mutect2
- LIN7A | c.483+13146A>G | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- MIR507 | n.48G>C | RNA (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- MIR518F | n.58C>A | RNA (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- N4BP2L1 | c.473+57A>T | Intron (SNP) | VAF 32/49 reads (65%) | catalogued as rs890318556; called by muse, mutect2, varscan2
- PPP3CA | c.58+16431C>G | Intron (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- SMPD1 | c.1091+37_1091+40del | Intron (DEL) | VAF 10/21 reads (48%) | called by pindel, varscan2
- UBTFL2 | n.743T>A | RNA (SNP) | VAF 27/255 reads (11%) | called by muse, mutect2, varscan2
